HCMI case HCM-CSHL-0381-C20 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/723fd0ed-5223-41ef-8f09-677a1b3ca9d4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1971; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 46.8 years (17,107 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IIA; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes.
   Pathology details: Lymphatic invasion present: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Radiation, Intensity-Modulated Radiotherapy; Treatment intent type: Neoadjuvant; Days to treatment start: 88 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 234 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 299 days; Days to treatment end: 464 days (1.3 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Neoadjuvant; Days to treatment start: 315 days.
   Recorded as not given: adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Radiation Therapy, NOS, for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 683 days (1.9 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 459.

Molecular and laboratory tests
- CEA: 11.3.
- MLH1 (IHC): Negative.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Negative.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps / Obesity / Diverticulosis / Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 131 kg; Height: 167.6 cm; BMI: 47.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Rectal Cancer.

Biospecimens (3 samples)
- Sample HCM-CSHL-0381-C20-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0381-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
- Sample HCM-CSHL-0381-C20-86A: Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
